Somatic mutation profile of tumor specimen TCGA-28-1750-01A (aliquot TCGA-28-1750-01A-01W-0643-08) from TCGA case TCGA-28-1750, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 40.6 years (14,817 days).
Specimen TCGA-28-1750-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fea3d113-f41a-4d77-b6bc-323deacfcaa3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-28-1750-10A (Blood Derived Normal), aliquot TCGA-28-1750-10A-01W-0643-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/07dd1a69-3283-4bd1-9ce6-c2709c80fd51

The open-access MAF lists 49 somatic variants for this specimen: 31 protein-altering or splice-affecting, 17 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 17, Frame Shift Del 3, Splice Site 2, 3'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.389G>A p.R130Q | Missense Mutation (SNP) | VAF 89/168 reads (53%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs121909229, CM981670, CM991081, COSV64288376, COSV64288604, COSV64290765, COSV64291054; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AGPAT4 | c.770G>T p.R257M | Missense Mutation (SNP) | VAF 26/141 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV100211163; called by muse, varscan2
- EPB42 | c.1394G>A p.R465H (on ENST00000441366 / NM_001114134.2; = p.R495H on NM_000119.3) | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs569683352, COSV100281881; called by muse, mutect2, varscan2
- FAT2 | c.7084G>A p.E2362K | Missense Mutation (SNP) | VAF 54/324 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV99942169; called by muse, mutect2, varscan2
- FBN2 | c.6670G>A p.G2224R | Missense Mutation (SNP) | VAF 33/205 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.645); catalogued as COSV52537401; called by muse, mutect2, varscan2
- KIF2B | c.1888G>A p.V630I | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.081); catalogued as rs913843372, COSV99275000; called by muse, mutect2
- KRT16 | c.1195G>C p.E399Q | Missense Mutation (SNP) | VAF 24/222 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as COSV100052882; called by muse, mutect2
- LILRB1 | c.1600C>T p.R534* (on ENST00000427581; = p.R484* on NM_006669.6) | Nonsense Mutation (SNP) | VAF 16/204 reads (8%) | catalogued as rs376266152; called by muse, mutect2
- LINS1 | c.1808C>A p.A603D | Missense Mutation (SNP) | VAF 20/296 reads (7%) | SIFT tolerated (0.34); PolyPhen benign (0.005); catalogued as COSV100130104; called by muse, mutect2
- MAGEB10 | c.470C>T p.S157F | Missense Mutation (SNP) | VAF 26/106 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100775222; called by muse, mutect2, varscan2
- MAP2K6 | c.952G>A p.E318K | Missense Mutation (SNP) | VAF 7/89 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV100765062; called by muse, mutect2
- MGAT4C | c.775T>C p.Y259H | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100152794; called by muse, mutect2, varscan2
- MXRA5 | c.74T>C p.L25P | Missense Mutation (SNP) | VAF 22/29 reads (76%) | SIFT tolerated (0.2); PolyPhen benign (0.445); catalogued as COSV99476252; called by muse, mutect2, varscan2
- NFS1 | c.968C>T p.S323L | Missense Mutation (SNP) | VAF 43/102 reads (42%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.506); catalogued as COSV100931885; called by muse, varscan2
- NLRP8 | c.367+2T>C p.X123_splice | Splice Site (SNP) | VAF 67/196 reads (34%) | catalogued as COSV99404976; called by muse, mutect2, varscan2
- NTRK3 | c.199G>A p.G67R | Missense Mutation (SNP) | VAF 1955/1986 reads (98%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.009); catalogued as COSV100446173; called by mutect2, varscan2
- OBP2B | c.304C>A p.Q102K | Missense Mutation (SNP) | VAF 8/196 reads (4%) | SIFT tolerated (0.21); PolyPhen benign (0.137); catalogued as COSV100922831; called by muse, mutect2
- OR4C15 | c.812A>G p.Y271C (on ENST00000314644; = p.Y217C on NM_001001920.2) | Missense Mutation (SNP) | VAF 45/247 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.105); catalogued as COSV100115508; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.2237C>T p.T746M (on ENST00000259318 / NM_001136562.3; = p.T977M on NM_007203.5) | Missense Mutation (SNP) | VAF 34/70 reads (49%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.557); catalogued as rs373087862; called by muse, mutect2, varscan2
- PPP1R9A | c.1489G>A p.V497I | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV99194997; called by muse, mutect2, varscan2
- RPGRIP1L | c.525G>T p.R175S | Missense Mutation (SNP) | VAF 9/168 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.021); catalogued as COSV100046081; called by muse, mutect2
- SH2D4B | c.407C>A p.A136D | Missense Mutation (SNP) | VAF 24/360 reads (7%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.786); catalogued as COSV100213706; called by muse, mutect2
- SLC39A13 | c.289C>A p.L97M | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100712654, COSV61521828; called by muse, mutect2
- TRAF5 | c.479C>A p.S160Y | Missense Mutation (SNP) | VAF 15/167 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99807289; called by muse, mutect2
- USF1 | c.557C>A p.S186Y | Missense Mutation (SNP) | VAF 8/158 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as COSV99230906; called by muse, mutect2
- WDR17 | c.2081T>C p.L694P | Missense Mutation (SNP) | VAF 12/138 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV54582402; called by muse, mutect2
- ARHGEF25 | c.915T>G p.F305L | Missense Mutation (SNP) | VAF 18/184 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.127); called by mutect2, varscan2
- IL6R | c.459_462del p.X153_splice | Splice Site (DEL) | VAF 12/40 reads (30%) | called by mutect2, pindel, varscan2
- MGAT2 | c.1319_1320del p.C440* | Frame Shift Del (DEL) | VAF 12/20 reads (60%) | called by mutect2, pindel, varscan2
- ZNF217 | c.2548del p.A850Hfs*12 | Frame Shift Del (DEL) | VAF 17/95 reads (18%) | called by mutect2, pindel, varscan2
- ZNF594 | c.2389del p.T797Lfs*324 | Frame Shift Del (DEL) | VAF 40/358 reads (11%) | called by pindel, varscan2
- ACP7 | c.1194G>A p.T398= | Silent (SNP) | VAF 8/45 reads (18%) | catalogued as rs1345264616, COSV58701567; called by muse, mutect2, varscan2
- ALKBH3 | c.588C>T p.P196= | Silent (SNP) | VAF 62/363 reads (17%) | catalogued as rs747645982, COSV100236187; called by mutect2, varscan2
- C4BPA | c.1761C>T p.S587= | Silent (SNP) | VAF 23/72 reads (32%) | catalogued as rs762923928, COSV100891174; called by muse, mutect2, varscan2
- CCDC105 | c.216C>A p.R72= | Silent (SNP) | VAF 4/9 reads (44%) | called by mutect2, varscan2
- CFAP298-TCP10L | c.972C>T p.A324= | Silent (SNP) | VAF 61/256 reads (24%) | catalogued as rs1426363011, COSV100291846; called by muse, mutect2, varscan2
- EPHB4 | c.2076C>T p.L692= | Silent (SNP) | VAF 16/86 reads (19%) | catalogued as COSV100639439; called by muse, varscan2
- EPHB4 | c.2052C>T p.T684= | Silent (SNP) | VAF 24/152 reads (16%) | catalogued as COSV100639452; called by muse, varscan2
- ESRRB | c.501G>A p.G167= | Silent (SNP) | VAF 89/428 reads (21%) | catalogued as COSV55064789; called by muse, mutect2, varscan2
- ITGB4 | c.549G>T p.T183= | Silent (SNP) | VAF 8/102 reads (8%) | catalogued as COSV99563694; called by muse, mutect2
- KLHL22 | c.1491G>A p.V497= | Silent (SNP) | VAF 43/132 reads (33%) | catalogued as COSV100185907; called by muse, mutect2, varscan2
- MAP7D2 | c.1866G>T p.G622= | Silent (SNP) | VAF 65/506 reads (13%) | catalogued as COSV101107264; called by muse, mutect2, varscan2
- NRDC | c.3552C>T p.T1184= | Silent (SNP) | VAF 16/274 reads (6%) | catalogued as COSV100543154; called by muse, mutect2
- OR13G1 | c.228G>A p.P76= | Silent (SNP) | VAF 14/54 reads (26%) | catalogued as rs371166459, COSV62943395; called by muse, mutect2, varscan2
- PELI2 | c.468C>T p.F156= | Silent (SNP) | VAF 10/64 reads (16%) | catalogued as rs371989404; called by muse, varscan2
- POLE3 | c.306C>T p.A102= | Silent (SNP) | VAF 124/194 reads (64%) | catalogued as COSV99928252; called by muse, mutect2, varscan2
- PTCH1 | c.3510G>A p.L1170= | Silent (SNP) | VAF 35/213 reads (16%) | catalogued as COSV100107997; called by muse, mutect2, varscan2
- TMPRSS9 | c.1233C>T p.D411= (on ENST00000648592; = p.D377= on NM_182973.2) | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as rs778597717, COSV60226643; called by muse, varscan2
- MFSD4B | c.*266C>T | 3'UTR (SNP) | VAF 5/32 reads (16%) | catalogued as rs758795099, COSV64349274; called by muse, mutect2, varscan2
